Gene-level copy-number profile of tumor specimen TCGA-62-A46S-01A from TCGA case TCGA-62-A46S, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.4 years (26,825 days).
Specimen TCGA-62-A46S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7eed573a-4367-48ef-ba5a-50813e859ecc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-A46S-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c56a24f2-1a90-4cad-b413-51ea4e8d5d0b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,399; copy number 3: 33,208; copy number 4: 14,888; copy number 5: 49; copy number 6: 1,252; copy number 7: 1; copy number 8: 17; copy number 9: 67; copy number 12: 254; copy number 13: 285; copy number 14: 32; copy number 16: 34; copy number 17: 104; copy number 18: 150; copy number 19: 36; copy number 20: 15; copy number 21: 3; copy number 22: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-A46S-01A-11D-A24C-01): tumor purity 0.45, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,024 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–545,781, 17 genes, copy number 8 (within-gene range 6–8): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP.
- chr8:63,384,839–85,481,493, 329 genes, copy number 13–22 (broad region; genes not listed).
- chr8:90,592,804–91,398,155, 16 genes, copy number 7–20: LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:121,954,640–126,329,538, 92 genes, copy number 12–19 (within-gene range 12–26) (broad region; genes not listed).
- chr8:126,556,323–127,419,050, 1 gene, copy number 14 (within-gene range 6–14): PCAT1.
- chr8:127,072,694–132,085,655, 61 genes, copy number 14–21 (within-gene range 2–21) (broad region; genes not listed).
- chr8:132,775,358–137,092,183, 52 genes, copy number 9 (within-gene range 3–9): PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1.
- chr8:137,105,352–145,066,685, 222 genes, copy number 9–13 (broad region; genes not listed).
- chr20:57,105,741–64,313,132, 234 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
